Somatic mutation profile of tumor specimen TCGA-LK-A4O2-01A (aliquot TCGA-LK-A4O2-01A-11D-A34C-32) from TCGA case TCGA-LK-A4O2, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 56.8 years (20,757 days).
Specimen TCGA-LK-A4O2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12cebe41-e807-4ead-87d9-084b763840a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LK-A4O2-10A (Blood Derived Normal), aliquot TCGA-LK-A4O2-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77bccbde-b0b4-4f60-befd-02548866b2f4

The open-access MAF lists 29 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 16, Silent 8, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAP1 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as rs1553645146, COSV56238008; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CCDC151 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as rs1356215589; called by muse, mutect2
- CELSR2 | c.7004C>T p.S2335L | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1205783788, COSV54771667; called by muse, mutect2, varscan2
- EIF4G3 | c.1847C>T p.T616I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV51686519; called by muse, mutect2, varscan2
- MAP2K2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV53566593; called by muse, mutect2, varscan2
- MCM3AP | c.3110C>T p.A1037V | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs150103441; called by muse, mutect2, varscan2
- MICALL2 | c.2656T>G p.S886A | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as rs774947153; called by muse, mutect2, varscan2
- SLC22A12 | c.334G>T p.D112Y | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV60574404; called by muse, mutect2, varscan2
- WSB1 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779961243; called by muse, mutect2, varscan2
- CYP4X1 | c.1240C>G p.H414D | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR32 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KDM3A | c.3450C>G p.I1150M | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KIF13B | c.2542A>T p.I848F | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MFHAS1 | c.860_863dup p.F288Lfs*18 | Frame Shift Ins (INS) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- PCGF1 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCLO | c.15322A>T p.K5108* | Nonsense Mutation (SNP) | VAF 31/148 reads (21%) | called by muse, mutect2, varscan2
- PTOV1 | c.1240-12_1241del p.X414_splice | Splice Site (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- SPECC1 | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STAMBPL1 | c.218del p.N73Mfs*10 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel
- UBN1 | c.824A>C p.E275A | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VASN | c.256A>G p.N86D | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC11 | c.586T>C p.L196= | Silent (SNP) | VAF 38/177 reads (21%) | catalogued as rs1452391235; called by muse, mutect2, varscan2
- CCDC88C | c.1716G>A p.S572= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as rs767670216; called by muse, mutect2, varscan2
- CLEC17A | c.423T>C p.S141= | Silent (SNP) | VAF 22/92 reads (24%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.9G>A p.Q3= | Silent (SNP) | VAF 24/56 reads (43%) | called by muse, mutect2
- NRDE2 | c.2247C>T p.H749= | Silent (SNP) | VAF 31/88 reads (35%) | called by muse, mutect2, varscan2
- RGS7 | c.456C>T p.S152= | Silent (SNP) | VAF 26/98 reads (27%) | catalogued as rs536502002; called by muse, mutect2, varscan2
- SALL1 | c.1446C>T p.C482= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs759286249, COSV51763155; called by muse, mutect2, varscan2
- TUBB4B | c.1081C>T p.L361= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
